Somatic mutation profile of tumor specimen C3L-08637-01 (aliquot CPT0481770006) from CPTAC case C3L-08637, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 70.8 years (25,865 days).
Specimen C3L-08637-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pylorus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 800727e8-1b27-41e9-a3a4-344f6f77f93c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-08637-32 (Blood Derived Normal), aliquot CPT0481920003; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/92e678fb-ddaf-40b2-add9-f43b7a877e64

The open-access MAF lists 132 somatic variants for this specimen: 92 protein-altering or splice-affecting, 35 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 78, Silent 35, Nonsense Mutation 8, Intron 4, Frame Shift Del 2, Frame Shift Ins 1, 5'Flank 1, Splice Region 1, Translation Start Site 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALOXE3 | c.631C>T p.R211* | Nonsense Mutation (SNP) | VAF 37/251 reads (15%) | catalogued as rs141340759, COSV59074643; ClinVar: pathogenic; called by muse, varscan2
- CTNNB1 | c.1004A>T p.K335I | Missense Mutation (SNP) | VAF 30/277 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV62688046, COSV62689047, COSV62695316; called by muse, mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 30/346 reads (9%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- AC099489.1 | c.1955G>A p.R652H | Missense Mutation (SNP) | VAF 34/440 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as rs1044525631, COSV60863886; called by muse, mutect2
- ADAMTS12 | c.1724A>C p.K575T | Missense Mutation (SNP) | VAF 20/184 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.292); catalogued as COSV61260128, COSV61272004; called by muse, mutect2
- ADAMTS5 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 41/292 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.026); catalogued as COSV53182004; called by muse, varscan2
- BRS3 | c.608G>A p.C203Y | Missense Mutation (SNP) | VAF 30/429 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1334522264; called by muse, mutect2
- C1GALT1C1L | c.206G>A p.R69H | Missense Mutation (SNP) | VAF 31/318 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.045); catalogued as rs559349613; called by muse, mutect2, varscan2
- CCDC88B | c.1334C>T p.A445V | Missense Mutation (SNP) | VAF 34/364 reads (9%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs756871869, COSV57266726; called by muse, mutect2
- CDON | c.3335G>A p.R1112Q | Missense Mutation (SNP) | VAF 47/342 reads (14%) | SIFT tolerated (0.5); PolyPhen benign (0.223); catalogued as rs1177628525, COSV54995613; called by muse, mutect2
- CNTN2 | c.820C>T p.R274C | Missense Mutation (SNP) | VAF 30/341 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs1473353987, COSV100085038; ClinVar: uncertain significance; called by muse, mutect2
- COL5A3 | c.3237G>A p.G1079= | Splice Region (SNP) | VAF 34/409 reads (8%) | catalogued as rs1208491762; called by muse, mutect2
- COL8A1 | c.200G>A p.G67D | Missense Mutation (SNP) | VAF 26/447 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV53732984; called by muse, mutect2
- CREB5 | c.1151G>A p.R384Q (on ENST00000357727 / NM_182898.4; = p.R377Q on NM_004904.3) | Missense Mutation (SNP) | VAF 46/443 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63226382; called by muse, mutect2, varscan2
- DNAH12 | c.5398C>T p.R1800* (on ENST00000351747; = p.R1819* on NM_001366028.2) | Nonsense Mutation (SNP) | VAF 32/412 reads (8%) | catalogued as rs1035349999, COSV61059035; called by muse, mutect2
- DNAH6 | c.5675G>A p.R1892Q | Missense Mutation (SNP) | VAF 33/299 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1194234737, COSV52867744; called by muse, mutect2, varscan2
- FKRP | c.1437G>C p.E479D | Missense Mutation (SNP) | VAF 42/500 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100586670; called by muse, mutect2
- FLCN | c.611C>T p.A204V | Missense Mutation (SNP) | VAF 16/222 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs766401197, CX080990; ClinVar: uncertain significance; called by muse, mutect2
- IL1R1 | c.1705G>A p.G569R | Missense Mutation (SNP) | VAF 13/196 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.033); catalogued as rs201681036, COSV52107374; called by muse, mutect2
- ITGA8 | c.1100G>A p.S367N | Missense Mutation (SNP) | VAF 36/410 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.006); catalogued as rs1268633635; called by muse, mutect2
- METTL22 | c.1120G>T p.V374L | Missense Mutation (SNP) | VAF 45/394 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.837); catalogued as COSV50837582; called by muse, mutect2
- ORAI2 | c.254C>T p.T85M | Missense Mutation (SNP) | VAF 55/290 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs745969579; called by muse, mutect2, varscan2
- PEG10 | c.382C>T p.R128C (on ENST00000482108 / NM_001040152.2; = p.R162C on NM_015068.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/486 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101509855; called by muse, mutect2
- PHIP | c.3457G>C p.D1153H | Missense Mutation (SNP) | VAF 34/244 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.818); catalogued as COSV51502019; called by muse, varscan2
- PKDREJ | c.514C>T p.R172W | Missense Mutation (SNP) | VAF 36/257 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.672); catalogued as rs772301557, COSV53546327; called by muse, mutect2, varscan2
- PTGIS | c.1136G>A p.R379H | Missense Mutation (SNP) | VAF 46/636 reads (7%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.862); catalogued as rs765709407, COSV99721325; called by muse, mutect2
- RAB19 | c.301C>T p.R101W | Missense Mutation (SNP) | VAF 80/439 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs527792086, COSV52044661; called by muse, mutect2, varscan2
- RADIL | c.2786C>T p.A929V | Missense Mutation (SNP) | VAF 43/423 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0.006); catalogued as rs373438367, COSV68199575; called by muse, mutect2, varscan2
- RASGRP1 | c.973G>A p.G325S | Missense Mutation (SNP) | VAF 29/205 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as rs372568458, COSV100172113; called by muse, mutect2, varscan2
- RBPJL | c.1339C>T p.R447C | Missense Mutation (SNP) | VAF 69/740 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1393715236; called by muse, mutect2
- REXO1 | c.1483C>T p.R495W | Missense Mutation (SNP) | VAF 51/428 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs774459639; called by muse, mutect2, varscan2
- RIMS1 | c.223A>C p.N75H | Missense Mutation (SNP) | VAF 37/407 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.05); catalogued as rs764174237; called by muse, mutect2
- SEMG1 | c.842G>A p.R281Q | Missense Mutation (SNP) | VAF 48/374 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs750800652, COSV54871925; called by muse, mutect2, varscan2
- SYNGAP1 | c.2669G>A p.R890H | Missense Mutation (SNP) | VAF 124/545 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.134); catalogued as rs369681579; called by muse, mutect2, varscan2
- TFF2 | c.10C>T p.R4* | Nonsense Mutation (SNP) | VAF 51/402 reads (13%) | catalogued as rs1204626263, COSV52295893; called by muse, mutect2, varscan2
- THSD7A | c.1981C>T p.R661* | Nonsense Mutation (SNP) | VAF 30/424 reads (7%) | catalogued as rs367816173, COSV70275503; called by muse, mutect2
- TPO | c.2725G>A p.A909T | Missense Mutation (SNP) | VAF 31/312 reads (10%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.014); catalogued as rs148789027; called by muse, mutect2
- TPX2 | c.1858A>G p.K620E | Missense Mutation (SNP) | VAF 21/423 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.275); catalogued as COSV55920500; called by muse, mutect2
- TRIM26 | c.530C>T p.A177V | Missense Mutation (SNP) | VAF 73/361 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.194); catalogued as rs765164788; called by muse, mutect2, varscan2
- TSPOAP1 | c.4289G>A p.R1430Q | Missense Mutation (SNP) | VAF 42/456 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1475598520, COSV99273313; called by muse, mutect2
- WDR17 | c.2994G>T p.E998D | Missense Mutation (SNP) | VAF 34/405 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.195); catalogued as rs577596460, COSV54573247; called by muse, mutect2
- ZNF292 | c.5429C>A p.S1810Y | Missense Mutation (SNP) | VAF 14/249 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.656); catalogued as COSV60539545; called by muse, mutect2
- ABCA1 | c.2855C>T p.P952L | Missense Mutation (SNP) | VAF 26/304 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- ABCB1 | c.560G>A p.G187D | Missense Mutation (SNP) | VAF 20/212 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ABCB7 | c.2259A>T p.*753Yext*3 (on ENST00000373394 / NM_001271696.3; = p.*754Yext*3 on NM_004299.6) | Nonstop Mutation (SNP) | VAF 22/320 reads (7%) | called by muse, mutect2
- AFF1 | c.1240A>C p.N414H | Missense Mutation (SNP) | VAF 29/251 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.218); called by muse, mutect2, varscan2
- AHI1 | c.1039G>C p.V347L | Missense Mutation (SNP) | VAF 26/350 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.745); called by muse, mutect2
- APC | c.4408_4418del p.A1470Cfs*13 | Frame Shift Del (DEL) | VAF 44/418 reads (11%) | called by mutect2, pindel
- BRINP3 | c.872G>T p.C291F | Missense Mutation (SNP) | VAF 20/320 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- BTNL8 | c.878A>T p.D293V (on ENST00000340184 / NM_001040462.3; = p.G336= on NM_024850.2) | Missense Mutation (SNP) | VAF 27/141 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- C1QTNF5 | c.408C>A p.Y136* | Nonsense Mutation (SNP) | VAF 61/605 reads (10%) | called by muse, mutect2
- CAPN10 | c.1187C>T p.A396V | Missense Mutation (SNP) | VAF 45/430 reads (10%) | SIFT tolerated (0.43); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CASS4 | c.1985G>T p.S662I | Missense Mutation (SNP) | VAF 74/332 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.153); called by muse, mutect2, varscan2
- CD101 | c.789_792dup p.I265Vfs*28 | Frame Shift Ins (INS) | VAF 36/350 reads (10%) | called by mutect2, pindel, varscan2
- CDH8 | c.1281T>G p.F427L | Missense Mutation (SNP) | VAF 23/212 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CDR2L | c.979G>A p.A327T | Missense Mutation (SNP) | VAF 62/469 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- DDIT4 | c.530T>A p.L177H | Missense Mutation (SNP) | VAF 59/470 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- DEPDC5 | c.3677G>A p.R1226K (on ENST00000400246; = p.R1295K on NM_014662.5) | Missense Mutation (SNP) | VAF 40/307 reads (13%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- DNAH14 | c.6848T>G p.L2283R (on ENST00000445597; = p.L2936R on NM_001367479.1) | Missense Mutation (SNP) | VAF 28/298 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2
- DUOX1 | c.1687G>C p.D563H | Missense Mutation (SNP) | VAF 11/294 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); called by muse, mutect2
- EFCAB13 | c.396G>T p.K132N | Missense Mutation (SNP) | VAF 26/293 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.624); called by muse, mutect2
- FASTK | c.442C>T p.R148* | Nonsense Mutation (SNP) | VAF 50/479 reads (10%) | called by muse, mutect2
- FIBIN | c.391T>G p.S131A | Missense Mutation (SNP) | VAF 44/440 reads (10%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- FN3K | c.877G>T p.G293W | Missense Mutation (SNP) | VAF 30/343 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FRMD3 | c.361G>T p.E121* | Nonsense Mutation (SNP) | VAF 31/232 reads (13%) | called by muse, mutect2, varscan2
- GABBR2 | c.330C>G p.N110K | Missense Mutation (SNP) | VAF 25/352 reads (7%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.996); called by muse, mutect2
- IQCK | c.467G>A p.C156Y | Missense Mutation (SNP) | VAF 25/238 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- JPH2 | c.1114G>T p.G372C | Missense Mutation (SNP) | VAF 52/701 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- LRP1B | c.7427A>G p.H2476R | Missense Mutation (SNP) | VAF 21/261 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.039); called by muse, mutect2
- LRRC36 | c.1973C>A p.A658D | Missense Mutation (SNP) | VAF 34/348 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.075); called by muse, varscan2
- MARK2 | c.1660G>T p.E554* (on ENST00000402010 / NM_001039469.2; = p.E520* on NM_017490.4) | Nonsense Mutation (SNP) | VAF 34/376 reads (9%) | called by muse, mutect2
- MOV10L1 | c.3131T>C p.L1044P | Missense Mutation (SNP) | VAF 59/422 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); called by muse, mutect2, varscan2
- MUC16 | c.1614G>T p.E538D | Missense Mutation (SNP) | VAF 46/491 reads (9%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.101); called by muse, mutect2
- MYO18B | c.3325C>G p.L1109V | Missense Mutation (SNP) | VAF 26/315 reads (8%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.544); called by muse, mutect2
- NPAS3 | c.2388G>T p.L796F (on ENST00000356141 / NM_001164749.2; = p.L764F on NM_022123.3) | Missense Mutation (SNP) | VAF 22/328 reads (7%) | SIFT tolerated, low confidence (0.24); PolyPhen probably damaging (0.916); called by muse, mutect2
- PGM1 | c.523T>C p.F175L | Missense Mutation (SNP) | VAF 39/348 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- PHF20 | c.1487C>A p.T496N | Missense Mutation (SNP) | VAF 58/656 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2
- POFUT1 | c.333G>C p.K111N | Missense Mutation (SNP) | VAF 49/534 reads (9%) | SIFT tolerated (0.37); PolyPhen benign (0.003); called by muse, mutect2
- RPS6KA6 | c.1291G>T p.D431Y | Missense Mutation (SNP) | VAF 26/380 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); called by muse, mutect2
- SCAPER | c.2050C>T p.R684W | Missense Mutation (SNP) | VAF 41/245 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SCNN1A | c.1509C>G p.F503L | Missense Mutation (SNP) | VAF 27/349 reads (8%) | SIFT tolerated (0.42); PolyPhen benign (0.255); called by muse, mutect2
- SLC4A9 | c.2320C>T p.P774S (on ENST00000507527 / NM_001258428.2; = p.P750S on NM_031467.3) | Missense Mutation (SNP) | VAF 40/476 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SMURF2 | c.950del p.D317Afs*20 | Frame Shift Del (DEL) | VAF 49/397 reads (12%) | called by mutect2, pindel, varscan2
- SRFBP1 | c.985G>A p.D329N | Missense Mutation (SNP) | VAF 32/295 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- SYBU | c.259G>T p.V87L (on ENST00000276646 / NM_001099754.2; = p.V86L on NM_017786.6) | Missense Mutation (SNP) | VAF 57/331 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SYT9 | c.1055A>G p.D352G | Missense Mutation (SNP) | VAF 28/249 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- TBRG4 | c.242G>A p.R81K | Missense Mutation (SNP) | VAF 58/570 reads (10%) | SIFT tolerated (0.79); PolyPhen benign (0.035); called by muse, mutect2
- TRAF3 | c.645G>T p.R215S | Missense Mutation (SNP) | VAF 36/231 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TRIM24 | c.2515C>T p.L839F (on ENST00000343526 / NM_015905.3; = p.L805F on NM_003852.4) | Missense Mutation (SNP) | VAF 28/334 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2
- TTN | c.56729C>T p.A18910V (on ENST00000591111; = p.A11486V on NM_003319.4) | Missense Mutation (SNP) | VAF 36/365 reads (10%) | PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- USP47 | c.529T>C p.S177P (on ENST00000399455 / NM_001372095.1; = p.S89P on NM_017944.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/281 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.018); called by muse, mutect2
- ZNF594 | c.1698A>C p.K566N | Missense Mutation (SNP) | VAF 33/259 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- ACTL10 | c.720G>C p.L240= | Silent (SNP) | VAF 16/355 reads (5%) | called by muse, mutect2
- ADAM22 | c.96A>G p.S32= | Silent (SNP) | VAF 21/293 reads (7%) | called by muse, mutect2
- ADCY1 | c.2754G>A p.K918= | Silent (SNP) | VAF 35/416 reads (8%) | catalogued as COSV99812886; called by muse, mutect2
- AP1B1 | c.2229C>T p.G743= | Silent (SNP) | VAF 43/415 reads (10%) | catalogued as rs754954079; called by muse, mutect2, varscan2
- APLP1 | c.1116G>T p.L372= | Silent (SNP) | VAF 42/507 reads (8%) | called by muse, mutect2
- ARPP21 | c.681C>T p.T227= | Silent (SNP) | VAF 15/276 reads (5%) | catalogued as rs1219331956; called by muse, mutect2
- BMP6 | c.1107C>T p.H369= | Silent (SNP) | VAF 42/386 reads (11%) | catalogued as rs755810484, COSV51671807; called by muse, mutect2
- CIITA | c.1497C>T p.D499= | Silent (SNP) | VAF 40/407 reads (10%) | catalogued as rs772143212, COSV60853785; called by muse, mutect2, varscan2
- DIDO1 | c.4056C>T p.D1352= | Silent (SNP) | VAF 86/507 reads (17%) | catalogued as COSV56616772, COSV56617439; called by muse, mutect2, varscan2
- DOCK4 | c.1386C>T p.N462= | Silent (SNP) | VAF 33/475 reads (7%) | called by muse, mutect2
- FHAD1 | c.3141C>G p.V1047= | Silent (SNP) | VAF 32/312 reads (10%) | called by muse, varscan2
- FXYD1 | c.84G>A p.P28= | Silent (SNP) | VAF 22/306 reads (7%) | catalogued as rs758472074; called by muse, mutect2
- GNPAT | c.1179G>A p.L393= | Silent (SNP) | VAF 32/408 reads (8%) | called by muse, mutect2
- GRM2 | c.132C>T p.G44= | Silent (SNP) | VAF 32/441 reads (7%) | catalogued as COSV56585683; called by muse, mutect2
- IGHV2-26 | c.114G>A p.T38= | Silent (SNP) | VAF 67/333 reads (20%) | catalogued as rs782328202; called by muse, mutect2, varscan2
- MPEG1 | c.345C>A p.I115= | Silent (SNP) | VAF 34/311 reads (11%) | called by muse, mutect2, varscan2
- MYPN | c.75A>G p.R25= | Silent (SNP) | VAF 41/365 reads (11%) | called by muse, varscan2
- NCAM1 | c.705C>T p.C235= | Silent (SNP) | VAF 36/376 reads (10%) | catalogued as rs376337341; called by muse, mutect2
- ODAPH | c.117C>T p.D39= | Silent (SNP) | VAF 45/318 reads (14%) | catalogued as rs760304382, COSV61141158; called by muse, mutect2, varscan2
- OR4S2 | c.759T>G p.T253= | Silent (SNP) | VAF 36/183 reads (20%) | called by muse, mutect2, varscan2
- OR5F1 | c.78C>A p.I26= | Silent (SNP) | VAF 18/335 reads (5%) | called by muse, mutect2
- OR6N2 | c.474T>G p.S158= | Silent (SNP) | VAF 30/412 reads (7%) | catalogued as COSV59410628, COSV59411893; called by muse, mutect2
- PGK1 | c.39C>T p.D13= | Silent (SNP) | VAF 45/420 reads (11%) | catalogued as rs1233948507; called by muse, mutect2, varscan2
- PLCG2 | c.2121C>T p.S707= | Silent (SNP) | VAF 35/381 reads (9%) | catalogued as rs527809751; ClinVar: likely benign; called by muse, mutect2
- POMT1 | c.129C>T p.D43= | Silent (SNP) | VAF 16/171 reads (9%) | catalogued as rs200465419; ClinVar: conflicting interpretations of pathogenicity / likely benign / uncertain significance; called by muse, mutect2
- PPP1R12A | c.582G>A p.R194= | Silent (SNP) | VAF 32/402 reads (8%) | called by muse, mutect2
- PTPN14 | c.1584G>A p.P528= | Silent (SNP) | VAF 40/462 reads (9%) | catalogued as rs564427221, COSV65283431, COSV65287706; called by muse, mutect2
- RFTN1 | c.1314C>A p.I438= | Silent (SNP) | VAF 18/284 reads (6%) | called by muse, mutect2
- SALL3 | c.1497C>T p.Y499= | Silent (SNP) | VAF 66/558 reads (12%) | catalogued as rs1477108765, COSV73306016; called by muse, mutect2, varscan2
- SLC4A9 | c.2319G>A p.L773= (on ENST00000507527 / NM_001258428.2; = p.L749= on NM_031467.3) | Silent (SNP) | VAF 40/474 reads (8%) | called by muse, mutect2
- SYN1 | c.1770G>A p.P590= | Silent (SNP) | VAF 63/702 reads (9%) | called by muse, mutect2
- TENM1 | c.2013T>A p.T671= | Silent (SNP) | VAF 58/552 reads (11%) | catalogued as COSV64425148, COSV64437386; called by muse, mutect2, varscan2
- WNT3A | c.327G>A p.S109= | Silent (SNP) | VAF 22/317 reads (7%) | catalogued as rs373278590; called by muse, mutect2
- ZNF679 | c.798A>G p.K266= | Silent (SNP) | VAF 13/418 reads (3%) | called by muse, mutect2
- ZNF865 | c.2757G>A p.L919= | Silent (SNP) | VAF 54/534 reads (10%) | called by muse, mutect2, varscan2
- ADGRA1 | c.4-1256A>C | Intron (SNP) | VAF 37/365 reads (10%) | catalogued as COSV66931135; called by muse, mutect2, varscan2
- COL6A2 | c.2462-2652C>T | Intron (SNP) | VAF 44/518 reads (8%) | catalogued as rs756694629, COSV56001712; called by muse, mutect2
- FAM25BP | chr10:46369159 G>A | 5'Flank (SNP) | VAF 51/413 reads (12%) | catalogued as rs1320799975; called by muse, mutect2, varscan2
- G6PD | c.-8-650G>A | Intron (SNP) | VAF 40/424 reads (9%) | catalogued as rs1330066266; called by muse, mutect2
- ZNF879 | c.34-9C>A | Intron (SNP) | VAF 51/510 reads (10%) | catalogued as rs764645394; called by muse, mutect2, varscan2
